Somatic mutation profile of tumor specimen ALCH-ABBM-TTP1-A (aliquot ALCH-ABBM-TTP1-A-1-0-D-A485-36) from ALCHEMIST case ALCH-ABBM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.2 years (28,932 days).
Specimen ALCH-ABBM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6733156a-7e83-45db-ba0f-c8dc0e3c4e8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABBM-NB1-A (Blood Derived Normal), aliquot ALCH-ABBM-NB1-A-2-0-D-A485-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8965b57-9b3c-461f-8191-4529492c11de

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 7, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 144/459 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 36/202 reads (18%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP6 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 23/321 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1369184353, COSV100498612; called by muse, mutect2
- CACNA1F | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1557105895; called by muse, mutect2
- CCDC7 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53231459; called by muse, mutect2
- CDK4 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1060501932; ClinVar: uncertain significance; called by muse, mutect2
- DMGDH | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs145775047; called by muse, mutect2, varscan2
- FAT3 | c.13573G>A p.D4525N | Missense Mutation (SNP) | VAF 48/513 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs61901507; called by muse, mutect2
- GAL3ST2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1343893552; called by muse, mutect2, varscan2
- JAK1 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61086725; called by muse, mutect2, varscan2
- KDM6A | c.3332G>A p.R1111H | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65036955; called by muse, mutect2
- LMX1A | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54217446; called by muse, mutect2
- NINL | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV99626390; called by muse, mutect2, varscan2
- OGT | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101035107; called by muse, mutect2, varscan2
- OR2T10 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV57898649; called by muse, mutect2
- PLA1A | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140761557; called by mutect2, varscan2
- RPS6KA2 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768306540, COSV55831483; called by mutect2, varscan2
- SEC13 | c.164+1del p.X55_splice (on ENST00000350697 / NM_183352.3; = p.X58_splice on NM_030673.4) | Splice Site (DEL) | VAF 9/71 reads (13%) | catalogued as rs1372933392; called by mutect2, pindel, varscan2
- SERPINA11 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs765626368; called by muse, mutect2, varscan2
- VEGFC | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1306316719, COSV54595552; called by muse, mutect2
- ALAS2 | c.924C>A p.D308E | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ATRX | c.5697+2T>C p.X1899_splice | Splice Site (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2, varscan2
- CADM1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCAF8 | c.677A>G p.Q226R | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GJC2 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KRIT1 | c.867T>G p.D289E | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.015); called by muse, mutect2
- LSM14A | c.60C>G p.I20M | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- MID2 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2
- NOTCH4 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, varscan2
- RGS21 | c.441dup p.W148Mfs*13 | Frame Shift Ins (INS) | VAF 8/87 reads (9%) | called by mutect2, pindel
- RNF13 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- SPATA31A1 | c.3197T>C p.M1066T | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TERF2 | c.1364G>T p.S455I | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TULP2 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- VWDE | c.3617G>T p.C1206F | Missense Mutation (SNP) | VAF 21/375 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF446 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF451 | c.1353_1356del p.K452Ifs*16 | Frame Shift Del (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- ZNF777 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, varscan2
- ADAMTS12 | c.2937C>T p.C979= | Silent (SNP) | VAF 35/414 reads (8%) | catalogued as rs944632546, COSV61265817; called by muse, mutect2
- CD81 | c.657G>A p.E219= | Silent (SNP) | VAF 22/261 reads (8%) | catalogued as rs1235761210; called by muse, mutect2
- DNAH7 | c.9054T>C p.P3018= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV56764628; called by muse, mutect2, varscan2
- OR2T10 | c.624G>C p.L208= | Silent (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- PHKA2 | c.903T>C p.Y301= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- SGTB | c.225A>T p.S75= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- SPICE1 | c.1833A>G p.E611= | Silent (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- DDX23 | c.*169C>T | 3'UTR (SNP) | VAF 28/322 reads (9%) | called by muse, mutect2
- DNASE1L1 | chrX:154398301 G>A | 3'Flank (SNP) | VAF 30/362 reads (8%) | catalogued as rs782204308; called by muse, mutect2
